Gene-level copy-number profile of tumor specimen ALCH-B41A-TTP1-A from ALCHEMIST case ALCH-B41A, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 73.6 years (26,894 days).
Specimen ALCH-B41A-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 4693b36f-648d-41ae-8a7a-91b1ce27d1c0.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B41A-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,727 have no estimate.
https://portal.gdc.cancer.gov/files/e3023683-e320-4db8-b30f-4e20e327ee4d

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 37; copy number 1: 14,969; copy number 2: 38,346; copy number 3: 4,089; copy number 4: 1,341; copy number 5: 106; copy number 6: 1; copy number 7: 1; copy number 8: 1; copy number 9: 5.

Homozygous deletions (total copy number 0; autosomes only): 32 genes in 10 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:156,242,184–156,248,117, 2 genes (within-gene range 0–2): BGLAP, PAQR6.
- chr4:3,901,566–3,902,594, 1 gene: OR7E162P.
- chr4:4,267,701–4,290,154, 1 gene: LYAR.
- chr4:68,509,441–68,670,652, 6 genes (within-gene range 0–2): UGT2B29P, UGT2B17, AC147055.2, AC147055.4, AC147055.3, UGT2B15.
- chr7:158,027,373–158,031,128, 1 gene (within-gene range 0–2): AC011899.1.
- chr13:19,152,567–19,187,618, 4 genes: SMPD4P2, AL139327.3, TUBA3C, AL139327.1.
- chr15:43,106,225–43,266,928, 11 genes: AC068724.3, AC068724.2, RPS3AP47, TMEM62, SPCS2P1, AC068724.4, AC068724.1, CCNDBP1, EPB42, TGM5, Y_RNA.
- chr19:54,589,441–54,608,376, 3 genes (within-gene range 0–1): AC245036.5, LILRA1, AC245036.4.
- chr21:9,082,601–9,083,101, 1 gene (within-gene range 0–1): SOWAHCP2.
- chr22:36,847,372–36,878,017, 2 genes: NCF4-AS1, NCF4.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 114 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:109,792,758–109,985,124, 5 genes, copy number 9 (within-gene range 4–9): RGPD5, LIMS3, AC013271.1, AC013268.1, AC013268.5.
- chr15:21,405,401–22,095,857, 35 genes, copy number 5–8 (within-gene range 0–8): POTEB3, MIR3118-3, U6, NF1P9, MIR5701-2, AC183088.4, AC183088.2, AC183088.1, LINC02203, AC183088.3, AC135068.6, AC135068.2, AC135068.12, AC135068.11, AC135068.1, AC135068.4, AC135068.5, AC135068.8, AC135068.7, AC135068.9, AC135068.10, AC135068.3, AC134981.1, MIR3118-4, POTEB, RNU6-631P, ZNF519P3, NF1P2, MIR5701-3, OR11J6P, AC134980.1, OR11H3P, AC134980.2, OR11K1P, OR4Q1P.
- chr15:22,070,241–22,095,472, 2 genes, copy number 5 (within-gene range 0–6): OR4M2, OR4N4.
- chr19:38,815,422–39,846,379, 71 genes, copy number 5 (broad region; genes not listed).
- chr21:43,092,956–43,107,570, 1 gene, copy number 7: U2AF1.

Autosomal genes at a single copy (total copy number 1): 14,416. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
